TCGA case TCGA-FR-A8YE — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a0bb7e56-85e1-4bc7-9515-f4279356e6d1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Alive.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 49.1 years (17,930 days); Days to diagnosis: 2,771 days (7.6 years); Prior treatment: No; Days to last follow up: 3,176 days (8.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Trunk; Ulceration indicator: No.
   Pathology details: Breslow thickness category: <=1 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 41.5 years (15,159 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 2,871 days (7.9 years); Disease response: Tumor Free.
- Days to follow up: 3,176 days (8.7 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 175 cm; BMI: 25.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FR-A8YE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 490 mg.
  Slide TCGA-FR-A8YE-06A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-FR-A8YE-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FR-A8YE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 0.79; Primary melanoma tumor ulceration: No; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,176 days; disease-specific survival: no event (censored), 3,176 days; progression-free interval: no event (censored), 3,176 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FR-A8YE-06A-11D-A371-01): tumor purity 0.21, ploidy 2.08, whole-genome doublings 0.
